Somatic mutation profile of tumor specimen C3N-02763-01 (aliquot CPT0184240012) from CPTAC case C3N-02763, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 76.6 years (27,965 days).
Specimen C3N-02763-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 908d401c-5963-457f-8451-4ec6e2833478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02763-71 (Blood Derived Normal), aliquot CPT0184300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdaebed7-a3c4-49e8-a498-5ad16072af5f

The open-access MAF lists 111 somatic variants for this specimen: 76 protein-altering or splice-affecting, 16 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Frame Shift Del 11, Intron 10, 5'UTR 3, Frame Shift Ins 3, Nonsense Mutation 3, 3'UTR 2, Splice Region 2, RNA 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.333C>G p.S111R | Missense Mutation (SNP) | VAF 159/396 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs765978945, CM951281, COSV56542656, COSV56544837, COSV56553040, COSV56574177; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs878955326; called by muse, mutect2, varscan2
- CDC27 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs1283418426; called by muse, mutect2, varscan2
- CDH18 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as COSV56935286; called by muse, mutect2
- CHST8 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as COSV52862895; called by muse, mutect2, varscan2
- CPSF4 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1401143481; called by muse, mutect2, varscan2
- EID2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1375930556; called by muse, mutect2, varscan2
- ERAP2 | c.210del p.S71Vfs*61 | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | catalogued as COSV65939342; called by mutect2, pindel, varscan2
- GINS2 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs1457228480; called by muse, mutect2
- HRH2 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51576234; called by muse, mutect2, varscan2
- LGI3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs771072595; called by muse, mutect2, varscan2
- PCDHAC1 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as rs782605586; called by muse, mutect2, varscan2
- PITPNM2 | c.178C>G p.H60D | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99758056; called by muse, mutect2, varscan2
- PPID | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751192669; called by muse, mutect2, varscan2
- VN1R2 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs774213336; called by muse, mutect2, varscan2
- WWC1 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs780422567, COSV54651243; called by muse, mutect2, varscan2
- ABCA5 | c.3034del p.I1012Lfs*4 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.1389C>T p.G463= | Splice Region (SNP) | VAF 81/433 reads (19%) | called by muse, mutect2, varscan2
- AMOTL1 | c.1494G>T p.K498N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ANLN | c.2801T>G p.V934G | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF12 | c.3128T>A p.L1043Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCAR3 | c.2114T>A p.V705E | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BCORL1 | c.3799A>C p.K1267Q | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.569_570del p.D190Vfs*7 | Frame Shift Del (DEL) | VAF 38/346 reads (11%) | called by mutect2, pindel, varscan2
- CEP350 | c.8572G>C p.E2858Q | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHRD | c.2722C>A p.H908N | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CLMN | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CNOT7 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.4652del p.G1551Dfs*159 | Frame Shift Del (DEL) | VAF 106/398 reads (27%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.2389T>A p.S797T (on ENST00000616178 / NM_001291722.2; = p.S772T on NM_014376.4) | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CYP3A7 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DCP1B | c.1520del p.F507Sfs*65 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- DOCK5 | c.5486del p.G1829Afs*75 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by pindel, varscan2*
- EXO5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXI1 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXI1 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FRY | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 86/324 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- G6PC | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GYS1 | c.1219T>A p.S407T | Missense Mutation (SNP) | VAF 126/450 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- HRNR | c.8417G>T p.G2806V | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IREB2 | c.2076A>T p.E692D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.959); called by muse, varscan2
- KRIT1 | c.399C>G p.Y133* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- KRTAP5-3 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 98/784 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, varscan2
- MAP3K4 | c.1846T>A p.F616I | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MFSD2A | c.393-1G>A p.X131_splice (on ENST00000372809 / NM_001136493.3; = p.X118_splice on NM_032793.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2
- MOB2 | c.530_539del p.V177Afs*52 | Frame Shift Del (DEL) | VAF 69/305 reads (23%) | called by mutect2, pindel, varscan2
- MRPL15 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MSH4 | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRX1 | c.2129del p.P710Qfs*21 | Frame Shift Del (DEL) | VAF 45/229 reads (20%) | called by mutect2, pindel, varscan2
- OR8H3 | c.896dup p.N299Kfs*5 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- PCDH15 | c.1917G>A p.Q639= | Splice Region (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR3B | c.3211_3212del p.S1071Kfs*2 | Frame Shift Del (DEL) | VAF 79/419 reads (19%) | called by mutect2, pindel, varscan2
- POLRMT | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAPGEF3 | c.1217C>A p.P406Q (on ENST00000389212; = p.P364Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SAMM50 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA4D | c.1219del p.I407* | Frame Shift Del (DEL) | VAF 49/235 reads (21%) | called by mutect2, pindel, varscan2
- SETD2 | c.4282dup p.R1428Kfs*26 | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- SLC16A13 | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 52/239 reads (22%) | called by muse, mutect2, varscan2
- SLC22A25 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SLC35A2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC38A10 | c.1351A>T p.R451* | Nonsense Mutation (SNP) | VAF 77/306 reads (25%) | called by muse, mutect2, varscan2
- SOX6 | c.1593T>A p.N531K (on ENST00000528429 / NM_001145819.2; = p.N504K on NM_017508.3) | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- STARD6 | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- STEAP2 | c.991T>C p.Y331H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.819); called by muse, varscan2
- SYNE2 | c.16382A>G p.E5461G | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TACC3 | c.1808T>G p.F603C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TM9SF3 | c.1448T>C p.F483S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM63C | c.793T>A p.L265M | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRIP4 | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ULBP1 | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.241); called by muse, mutect2
- WASL | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR26 | c.1901T>G p.I634S (on ENST00000414423 / NM_001379403.1; = p.I534S on NM_025160.7) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF281 | c.2558_2559del p.S853* | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by pindel, varscan2
- ZNF354C | c.372T>G p.F124L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF688 | c.139dup p.Q47Pfs*37 | Frame Shift Ins (INS) | VAF 76/350 reads (22%) | called by mutect2, pindel, varscan2
- APOC2 | c.60C>A p.V20= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as COSV99376891; called by muse, mutect2, varscan2
- C1orf43 | c.48G>T p.V16= | Silent (SNP) | VAF 57/263 reads (22%) | catalogued as rs1286960916, COSV55167478; called by muse, mutect2, varscan2
- CDC42BPG | c.1833G>A p.K611= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- CHRNA5 | c.873T>A p.S291= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- FANCF | c.639T>G p.P213= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- FOXM1 | c.1644G>A p.Q548= | Silent (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- GALNT6 | c.933C>G p.P311= | Silent (SNP) | VAF 113/473 reads (24%) | catalogued as COSV62542202, COSV62542435; called by muse, mutect2, varscan2
- GINS2 | c.18C>A p.V6= | Silent (SNP) | VAF 58/282 reads (21%) | catalogued as COSV53680395; called by muse, mutect2
- KDM6A | c.1689T>C p.P563= | Silent (SNP) | VAF 163/330 reads (49%) | called by muse, mutect2, varscan2
- LRRC32 | c.1032G>C p.L344= | Silent (SNP) | VAF 74/429 reads (17%) | catalogued as COSV99476735; called by muse, mutect2, varscan2
- MSH4 | c.159T>C p.C53= | Silent (SNP) | VAF 89/459 reads (19%) | catalogued as rs1486528111; called by muse, mutect2, varscan2
- PARVA | c.939C>T p.F313= | Silent (SNP) | VAF 72/286 reads (25%) | called by muse, mutect2, varscan2
- RNF14 | c.726C>T p.Y242= | Silent (SNP) | VAF 106/385 reads (28%) | catalogued as rs779016312, COSV61662323; called by muse, mutect2, varscan2
- S1PR4 | c.615C>T p.I205= | Silent (SNP) | VAF 51/167 reads (31%) | called by muse, mutect2, varscan2
- SLC30A6 | c.453G>T p.T151= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV50872472; called by muse, varscan2
- UNC80 | c.5310C>G p.P1770= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2
- AC134312.1 | n.792T>A | RNA (SNP) | VAF 118/452 reads (26%) | called by muse, mutect2, varscan2
- ACAA1 | c.-7C>A | 5'UTR (SNP) | VAF 88/241 reads (37%) | catalogued as rs527905538; called by muse, mutect2, varscan2
- ACSL1 | c.310+174G>A | Intron (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- ANXA6 | c.*525G>C | 3'UTR (SNP) | VAF 207/448 reads (46%) | called by muse, mutect2, varscan2
- ATP5PO | c.441+614G>C | Intron (SNP) | VAF 82/304 reads (27%) | called by muse, mutect2, varscan2
- COMTD1 | c.447+16T>C | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as rs1294040991; called by muse, mutect2, varscan2
- CTBP1 | c.41-3183G>A | Intron (SNP) | VAF 47/213 reads (22%) | catalogued as COSV99338192; called by muse, mutect2, varscan2
- DAPK1 | c.1825-18T>C | Intron (SNP) | VAF 56/266 reads (21%) | called by muse, mutect2, varscan2
- DPP10 | c.61-147029T>C | Intron (SNP) | VAF 77/315 reads (24%) | called by muse, mutect2, varscan2
- FBXO38 | c.3388+25T>C | Intron (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- FOXP2 | chr7:114086479 C>A | 5'Flank (SNP) | VAF 39/162 reads (24%) | catalogued as rs778053968; called by muse, mutect2, varscan2
- NFX1 | c.3039+34del | Intron (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- PLEKHH1 | c.3933+279T>C | Intron (SNP) | VAF 49/226 reads (22%) | catalogued as rs748685356; called by muse, mutect2, varscan2
- RAPGEF6 | c.-9G>A | 5'UTR (SNP) | VAF 26/68 reads (38%) | catalogued as COSV99726340; called by muse, varscan2
- RAVER1 | chr19:10317458 A>T | 3'Flank (SNP) | VAF 106/414 reads (26%) | called by muse, mutect2, varscan2
- RNASEH2C | c.*13G>A | 3'UTR (SNP) | VAF 105/508 reads (21%) | called by muse, mutect2, varscan2
- SRP19 | c.-29G>A | 5'UTR (SNP) | VAF 74/441 reads (17%) | called by muse, mutect2, varscan2
- TMEM256 | c.117+11T>A | Intron (SNP) | VAF 46/173 reads (27%) | called by muse, mutect2, varscan2
- ZNF849P | n.1235A>T | RNA (SNP) | VAF 19/113 reads (17%) | called by muse, varscan2
